Somatic mutation profile of tumor specimen TCGA-D3-A2J6-06A (aliquot TCGA-D3-A2J6-06A-11D-A19A-08) from TCGA case TCGA-D3-A2J6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.6 years (25,074 days).
Specimen TCGA-D3-A2J6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb9f0f0e-e024-4150-af95-0b983c464ad5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2J6-10A (Blood Derived Normal), aliquot TCGA-D3-A2J6-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a45b932f-09df-43ca-a8d0-81401c0bc96d

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9L | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs765297594, COSV58321103; called by muse, mutect2, varscan2
- CDSN | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753468197, COSV52538220; called by muse, mutect2, varscan2
- HOMER1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV56530835; called by muse, varscan2
- LARS1 | c.1103C>T p.S368L (on ENST00000394434 / NM_020117.11; = p.S341L on NM_016460.3) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV50990755; called by mutect2, varscan2
- LILRB4 | c.1157A>G p.D386G (on ENST00000391733 / NM_001278428.3; = p.D385G on NM_001278426.3) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs780225278, COSV54408834; called by mutect2, varscan2
- NAPA | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV54552069; called by muse, mutect2, varscan2
- NCOA7 | c.1873A>G p.N625D | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV57660615; called by muse, mutect2, varscan2
- PRDM16 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.462); catalogued as COSV54609443; called by muse, mutect2, varscan2
- PTPN1 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65409697; called by muse, mutect2, varscan2
- SMG1 | c.7535T>C p.L2512P | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67174932; called by muse, mutect2, varscan2
- TAOK2 | c.2845C>T p.H949Y | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54241328; called by muse, mutect2, varscan2
- UPF1 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV53202192; called by mutect2, varscan2
- ZNF7 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV57385510; called by muse, mutect2, varscan2
- C4BPA | c.255C>T p.Y85= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs771022113, COSV65536131; called by mutect2, varscan2
- CA4 | c.450G>A p.S150= | Silent (SNP) | VAF 65/78 reads (83%) | catalogued as rs201148452, COSV56282842; called by muse, mutect2, varscan2
- G6PD | c.114T>G p.G38= | Silent (SNP) | VAF 42/197 reads (21%) | catalogued as COSV54839170; called by muse, mutect2, varscan2
- MYH1 | c.1161A>G p.A387= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as COSV56857593; called by muse, mutect2
- PCDH15 | c.978C>T p.I326= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs563269633, COSV57398868; called by muse, mutect2, varscan2
- PSG3 | c.246C>T p.Y82= | Silent (SNP) | VAF 133/344 reads (39%) | catalogued as rs375731618; called by muse, mutect2, varscan2
- RYR2 | c.3483C>T p.V1161= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs777622110, COSV63715632; ClinVar: likely benign; called by mutect2, varscan2
- ZNF35 | c.150G>A p.Q50= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV56077529, COSV99940201; called by muse, varscan2
- KATNIP | c.540+5902C>T | Intron (SNP) | VAF 103/288 reads (36%) | catalogued as rs1259224140, COSV99852099; called by muse, mutect2, varscan2
